Gene-level copy-number profile of tumor specimen TCGA-5P-A9JY-01A from TCGA case TCGA-5P-A9JY, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 79.1 years (28,881 days).
Specimen TCGA-5P-A9JY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.92ecd3dc-ad2b-4ec7-9765-df8511057cf7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5P-A9JY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ea957b2-0dde-4ec8-961d-e93dc8f20ef9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,944; copy number 1: 1,380; copy number 2: 42,617; copy number 3: 1,272; copy number 4: 12,048; copy number 5: 2; copy number 6: 9; copy number 7: 2; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5P-A9JY-01A-11D-A42I-01): tumor purity 0.85, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:41,265,339–41,271,835, 2 genes (within-gene range 0–4): KRTAP9-6, KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:158,703,287–158,703,460, 1 gene, copy number 5: AC005042.2.
- chr3:139,493,809–139,539,829, 2 genes, copy number 6: ACTG1P1, RBP1.
- chr7:63,011,463–63,176,019, 7 genes, copy number 6: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1.
- chr7:132,086,266–132,087,992, 1 gene, copy number 5: AC105443.1.
- chr13:19,026,001–19,032,626, 2 genes, copy number 7 (within-gene range 2–7): GTF2IP3, AL137001.1.
- chr16:65,861,112–65,863,784, 1 gene, copy number 10 (within-gene range 4–10): AC022164.1.

Autosomal genes at a single copy (total copy number 1): 1,380. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
